TCGA case TCGA-SC-A6LR — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b106d71c-7809-4efa-a969-ee1f93a44720

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Epithelioid mesothelioma, malignant: ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 73.3 years (26,773 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 1,168 days (3.2 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 83 days; Days to treatment end: 146 days; Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 182 days; Days to treatment end: 219 days; Treatment dose: 4,680 cGy; Treatment outcome: Stable Disease; Number of fractions: 26; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Antineoplastic Vaccine; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.

Follow-up (5 entries)
- Days to follow up: 524 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 895 days (2.5 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; Timepoint: Preoperative.
- Karnofsky performance status: 90; Timepoint: Post Adjuvant Therapy.
- Follow-up contact recording only the day: day 1,168.

Molecular and laboratory tests
- Serum Mesothelin 0.6 nmol/L [Blood test normal range lower: 0; Blood test normal range upper: 1.5].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.3].

Exposures
- Occupation type: Ships' Deck Crews and Related Workers.
- Exposure type: Asbestos; Exposure source: Occupational.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SC-A6LR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 480 mg.
  Slide TCGA-SC-A6LR-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-SC-A6LR-01A-02-TSB: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 70; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SC-A6LR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SC-A6LR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: Tumor free; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Naval ship work; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Serum mesothelin prior treatment: 0.6.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; New tumor event diagnosis indicator: No.
- Drug treatment 3: Clinical trial drug classification: WT1 Vaccine trial.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,168 days; disease-specific survival: no event (censored), 1,168 days; progression-free interval: no event (censored), 1,168 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SC-A6LR-01A-11D-A34B-01): tumor purity 0.57, ploidy 2.54, whole-genome doublings 0.
